Somatic mutation profile of tumor specimen TARGET-30-PAUCFI-01A (aliquot TARGET-30-PAUCFI-01A-01D) from TARGET case TARGET-30-PAUCFI, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 2.9 years (1,057 days).
Specimen TARGET-30-PAUCFI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b1b731b-0332-4dbd-b54e-e17dfd228f21.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUCFI-10A (Blood Derived Normal), aliquot TARGET-30-PAUCFI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e7e27ed-fcbb-4511-acdc-2c22e2d07a69

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 3, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3122C>A p.T1041N | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV66567921, COSV99070361; called by muse, mutect2, varscan2
- C11orf65 | c.*1286G>T | 3'UTR (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
- NPAP1 | c.*639G>T | 3'UTR (SNP) | VAF 27/110 reads (25%) | called by muse, mutect2, varscan2
- RAD50 | c.*317C>A | 3'UTR (SNP) | VAF 41/189 reads (22%) | catalogued as COSV54759817; called by muse, mutect2, varscan2
